Somatic mutation profile of tumor specimen TCGA-DU-7302-01A (aliquot TCGA-DU-7302-01A-11D-2086-08) from TCGA case TCGA-DU-7302, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 48.3 years (17,656 days).
Specimen TCGA-DU-7302-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80974458-b303-4e22-a4cb-9786340f5af3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7302-10A (Blood Derived Normal), aliquot TCGA-DU-7302-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf6b0fd7-dcae-478c-8c2a-910e4a3cbcaa

The open-access MAF lists 36 somatic variants for this specimen: 32 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Frame Shift Del 9, In Frame Del 5, Silent 4, Splice Site 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 40/108 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACSBG1 | c.668G>A p.W223* | Nonsense Mutation (SNP) | VAF 25/64 reads (39%) | catalogued as COSV51907559, COSV51910471; called by muse, mutect2, varscan2
- ADCY3 | c.1258G>A p.V420M | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1004579539, COSV53170059; called by muse, mutect2, varscan2
- CDH23 | c.5653C>T p.R1885C | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.234); catalogued as rs368848049, COSV56473647; ClinVar: uncertain significance; called by muse, mutect2
- CES3 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs148620443, COSV57593639; called by muse, mutect2, varscan2
- CLUH | c.1276_1278del p.F426del (on ENST00000435359; = p.F464del on NM_015229.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 11/52 reads (21%) | catalogued as rs1373538192; called by pindel, varscan2
- CNNM2 | c.1639A>G p.I547V | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as rs1480079135, COSV64002063; called by muse, mutect2
- FAM50A | c.914A>C p.K305T | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV50133041, COSV99340967; called by muse, mutect2
- FASLG | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60680960; called by muse, mutect2, varscan2
- FLNA | c.1508T>A p.F503Y | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV61051402; called by muse, mutect2
- FLNB | c.2199+1G>C p.X733_splice | Splice Site (SNP) | VAF 8/21 reads (38%) | catalogued as COSV55895005; called by muse, mutect2, varscan2
- KCNJ1 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs773713405, COSV60662790; called by muse, mutect2
- MYH2 | c.3415G>A p.E1139K | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55448051; called by muse, mutect2, varscan2
- RFXANK | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs368808881; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SOX3 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65168713; called by muse, mutect2, varscan2
- SPDYE1 | c.371_372del p.P124Rfs*3 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | catalogued as rs1396493364; called by mutect2, pindel, varscan2
- SUMF2 | c.670A>T p.K224* (on ENST00000652303; = p.K205* on NM_015411.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/161 reads (11%) | catalogued as COSV51918930; called by muse, mutect2, varscan2
- TGM7 | c.407C>T p.T136I | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs770861173, COSV71773154; called by muse, mutect2, varscan2
- TRIM54 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs748843079, COSV56085510; called by muse, mutect2, varscan2
- ANO9 | c.2237_2239del p.K746del | In Frame Del (DEL) | VAF 44/129 reads (34%) | called by pindel, varscan2
- ASL | c.910_913del p.F304Gfs*7 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | called by mutect2, pindel, varscan2
- BCOR | c.2233_2234del p.R745Efs*6 | Frame Shift Del (DEL) | VAF 44/179 reads (25%) | called by pindel, varscan2
- CIC | c.4054_4055del p.E1352Sfs*9 | Frame Shift Del (DEL) | VAF 53/141 reads (38%) | called by pindel, varscan2
- CIT | c.4181-2_4183del p.X1394_splice | Splice Site (DEL) | VAF 14/101 reads (14%) | called by mutect2, pindel, varscan2
- GNAI1 | c.1062_1063del p.F354Lfs*15 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- JARID2 | c.2471_2473del p.T824_F825delinsI | In Frame Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel, varscan2
- METTL3 | c.633_635del p.K212del | In Frame Del (DEL) | VAF 31/229 reads (14%) | called by mutect2, pindel, varscan2
- NDUFS3 | c.531_533del p.F178del | In Frame Del (DEL) | VAF 34/348 reads (10%) | called by pindel, varscan2
- NKX2-2 | c.809del p.Q270Rfs*47 | Frame Shift Del (DEL) | VAF 26/69 reads (38%) | called by mutect2, pindel, varscan2
- ZBTB18 | c.53_54del p.R18Tfs*7 | Frame Shift Del (DEL) | VAF 7/76 reads (9%) | called by pindel, varscan2
- ZNF292 | c.2598_2599del p.K867Rfs*10 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by pindel, varscan2
- ZNF292 | c.3032_3033del p.L1011Qfs*4 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by pindel, varscan2
- APOB | c.12015C>T p.A4005= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as rs995623758, COSV51951769; called by muse, mutect2, varscan2
- GATC | c.327C>T p.R109= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs763975149, COSV57571148; called by muse, mutect2, varscan2
- KLHL15 | c.1113A>G p.E371= | Silent (SNP) | VAF 98/223 reads (44%) | catalogued as COSV60142027; called by muse, mutect2, varscan2
- PGAP6 | c.426C>T p.S142= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs755283177, COSV51742486; called by muse, mutect2, varscan2
